Somatic mutation profile of cancer-model specimen HCM-BROD-0014-C71-85B (Adherent Cell Line, passage 10; aliquot HCM-BROD-0014-C71-85B-01D-A77E-36), derived from the primary tumor of HCMI case HCM-BROD-0014-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.3 years (24,957 days).
Specimen HCM-BROD-0014-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4abf6d87-2f3c-4d52-93cc-53075d9fffc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0014-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0014-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96c82f0b-778d-42e8-ac20-b29d1b1895b6

The open-access MAF lists 90 somatic variants for this specimen: 56 protein-altering or splice-affecting, 22 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 22, Intron 4, 3'UTR 4, Frame Shift Del 2, RNA 1, 3'Flank 1, 5'Flank 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.3087C>A p.S1029R | Missense Mutation (SNP) | VAF 100/192 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); catalogued as COSV51408621; called by muse, mutect2, varscan2
- ANKRD24 | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 162/508 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs866794284, COSV53668949; called by muse, mutect2, varscan2
- C11orf95 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs989786394; called by muse, mutect2, varscan2
- C3 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 298/959 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs147549358, COSV55572426; called by muse, mutect2, varscan2
- CCDC154 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 172/335 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs769618310; called by muse, mutect2, varscan2
- CDH17 | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.459); catalogued as rs201729274, COSV50327363; called by muse, mutect2, varscan2
- CIT | c.5879G>A p.R1960H | Missense Mutation (SNP) | VAF 168/364 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.925); catalogued as rs1174828844, COSV99949344, COSV99950240; called by muse, mutect2, varscan2
- CSAG3 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 646/1406 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs1365577266; called by muse, mutect2, varscan2
- EGFR | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 114/1568 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.766); catalogued as COSV99295901; called by muse, mutect2
- FAM205A | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 188/423 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.085); catalogued as rs1043319691; called by muse, mutect2, varscan2
- GRIK4 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 100/182 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985387728; called by muse, mutect2, varscan2
- IRF2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs761561042, COSV66928939; called by muse, mutect2, varscan2
- ITIH5 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs747038918, COSV53670364; called by muse, mutect2, varscan2
- KCNJ15 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 86/172 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157297131, COSV100154056; called by muse, mutect2, varscan2
- LPCAT4 | c.352C>A p.R118S | Missense Mutation (SNP) | VAF 31/415 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as rs751209708; called by muse, mutect2
- MMP9 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 238/552 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs1284222372; called by muse, mutect2, varscan2
- MSMB | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 69/69 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs370848479; called by muse, mutect2, varscan2
- MYRF | c.2081C>T p.T694M (on ENST00000278836 / NM_001127392.3; = p.T685M on NM_013279.4) | Missense Mutation (SNP) | VAF 152/345 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs760054506, COSV53886651; called by muse, mutect2, varscan2
- NME8 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200863038, COSV52246730, COSV99553828; called by muse, mutect2, varscan2
- NME8 | c.1163T>C p.L388S | Missense Mutation (SNP) | VAF 102/357 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52252047; called by muse, mutect2, varscan2
- OR13C2 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 114/243 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370289806; called by muse, mutect2, varscan2
- PHLDB3 | c.1087G>A p.V363M | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs758852591, COSV52667775; called by muse, mutect2, varscan2
- PMS2 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 198/674 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs138387687; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- PTER | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 119/119 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs768587003, COSV54344488; called by muse, mutect2, varscan2
- RBM44 | c.1045G>A p.V349I (on ENST00000611254; = p.V983I on NM_001080504.2) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs780466978; called by muse, mutect2, varscan2
- RNF213 | c.12098C>T p.P4033L | Missense Mutation (SNP) | VAF 272/604 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778482758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.13093G>A p.D4365N | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.335); catalogued as rs372880584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SV2C | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs759085527, COSV59227182; called by muse, mutect2, varscan2
- SYT6 | c.1211C>A p.S404Y (on ENST00000610222 / NM_001366225.1; = p.S319Y on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.905); catalogued as COSV101059658; called by muse, mutect2, varscan2
- VN1R2 | c.760A>G p.S254G | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV59038327; called by muse, mutect2
- ZNF618 | c.884C>T p.T295M (on ENST00000374126 / NM_001318042.2; = p.T263M on NM_001318040.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 153/285 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.321); catalogued as rs1367764187; called by muse, mutect2, varscan2
- ZNF92 | c.1093G>A p.G365R (on ENST00000328747 / NM_152626.4; = p.G296R on NM_007139.4) | Missense Mutation (SNP) | VAF 103/417 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV100165919; called by muse, mutect2, varscan2
- AFF2 | c.523A>G p.S175G | Missense Mutation (SNP) | VAF 225/225 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP2S1 | c.428G>T p.*143Lext*35 | Nonstop Mutation (SNP) | VAF 280/611 reads (46%) | called by muse, mutect2, varscan2
- ATF7 | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 121/255 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- B4GALT7 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL11A1 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 207/470 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDX53 | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- DHX16 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 138/309 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DIP2B | c.4682G>T p.S1561I | Missense Mutation (SNP) | VAF 152/359 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- EIF4EBP1 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 147/305 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EMB | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- EXOC7 | c.360G>C p.Q120H | Missense Mutation (SNP) | VAF 117/249 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- IL4R | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 120/310 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- KANK2 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KDM5D | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 110/111 reads (99%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- MBD3 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 288/918 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- MRGPRX4 | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 174/368 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MUC3A | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 119/428 reads (28%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2, varscan2
- PBRM1 | c.206del p.C69Lfs*26 | Frame Shift Del (DEL) | VAF 77/104 reads (74%) | called by mutect2, pindel, varscan2
- PPIE | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PRKG2 | c.2023A>G p.I675V | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SLC10A5 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.225); called by muse, mutect2
- TJP3 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ZBTB21 | c.1329C>G p.I443M | Missense Mutation (SNP) | VAF 168/337 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF708 | c.156del p.I53Sfs*13 | Frame Shift Del (DEL) | VAF 42/195 reads (22%) | called by mutect2, pindel, varscan2
- ABCC2 | c.2781G>A p.L927= | Silent (SNP) | VAF 194/194 reads (100%) | catalogued as rs753596504; called by muse, mutect2, varscan2
- AEBP1 | c.3162C>T p.P1054= | Silent (SNP) | VAF 163/544 reads (30%) | catalogued as rs113676804; called by muse, mutect2, varscan2
- ARHGAP9 | c.177C>T p.S59= | Silent (SNP) | VAF 305/663 reads (46%) | catalogued as rs749278369, COSV62724665; called by muse, mutect2, varscan2
- BCAT2 | c.111G>A p.L37= | Silent (SNP) | VAF 173/328 reads (53%) | called by muse, mutect2, varscan2
- C2CD2 | c.1857C>T p.A619= | Silent (SNP) | VAF 135/285 reads (47%) | called by muse, mutect2, varscan2
- CELSR3 | c.7803G>A p.V2601= | Silent (SNP) | VAF 28/28 reads (100%) | catalogued as rs1465222095; called by muse, varscan2
- DNAJA2 | c.258T>C p.D86= | Silent (SNP) | VAF 76/192 reads (40%) | called by muse, mutect2, varscan2
- DRC7 | c.2277G>A p.P759= | Silent (SNP) | VAF 72/168 reads (43%) | catalogued as rs201527035, COSV100395742; called by muse, mutect2
- EXOC3L2 | c.1974A>G p.Q658= | Silent (SNP) | VAF 119/516 reads (23%) | called by muse, mutect2, varscan2
- FER1L6 | c.2253A>G p.K751= | Silent (SNP) | VAF 111/241 reads (46%) | called by muse, mutect2, varscan2
- LDB3 | c.1785C>T p.N595= | Silent (SNP) | VAF 141/141 reads (100%) | catalogued as rs757550916; called by muse, mutect2, varscan2
- LOXL2 | c.1779C>T p.Y593= | Silent (SNP) | VAF 56/141 reads (40%) | catalogued as rs1329594914; called by muse, mutect2, varscan2
- LRBA | c.7464C>T p.P2488= | Silent (SNP) | VAF 95/203 reads (47%) | called by muse, mutect2, varscan2
- MAPK9 | c.1176G>A p.S392= | Silent (SNP) | VAF 66/165 reads (40%) | catalogued as rs200820257; called by muse, mutect2, varscan2
- NPTX1 | c.819C>T p.Y273= | Silent (SNP) | VAF 223/502 reads (44%) | catalogued as rs143365668; called by muse, mutect2, varscan2
- OR4D6 | c.609C>T p.N203= | Silent (SNP) | VAF 118/238 reads (50%) | catalogued as rs758028167, COSV55658915; called by muse, mutect2, varscan2
- PCYOX1L | c.702G>A p.G234= | Silent (SNP) | VAF 73/136 reads (54%) | called by muse, mutect2, varscan2
- PMS2 | c.2151G>A p.V717= | Silent (SNP) | VAF 88/419 reads (21%) | called by muse, mutect2, varscan2
- POTED | c.966T>C p.N322= | Silent (SNP) | VAF 13/17 reads (76%) | called by mutect2, varscan2
- SKP2 | c.483T>C p.I161= | Silent (SNP) | VAF 142/299 reads (47%) | called by muse, mutect2, varscan2
- SVOPL | c.732C>T p.R244= (on ENST00000419765; = p.R92= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 139/472 reads (29%) | catalogued as rs765138699, COSV55993517; called by muse, mutect2, varscan2
- USP38 | c.153G>A p.E51= | Silent (SNP) | VAF 81/190 reads (43%) | catalogued as rs749030582; called by muse, mutect2, varscan2
- APCDD1 | c.-279G>A | 5'UTR (SNP) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- ATG2A | c.*216G>A | 3'UTR (SNP) | VAF 124/222 reads (56%) | called by muse, mutect2, varscan2
- C4A | chr6:32007447 del T | 3'Flank (DEL) | VAF 113/586 reads (19%) | catalogued as rs369404825; called by mutect2, varscan2
- COLEC12 | c.*1C>T | 3'UTR (SNP) | VAF 88/184 reads (48%) | catalogued as rs749935302, COSV68372109; called by muse, mutect2, varscan2
- DNAH10 | c.1816-2668C>T | Intron (SNP) | VAF 40/94 reads (43%) | catalogued as rs75803525; called by muse, mutect2, varscan2
- EFHC1 | c.*3009G>A | 3'UTR (SNP) | VAF 196/387 reads (51%) | called by muse, mutect2, varscan2
- EIF2B4 | c.419-13_419-11del | Intron (DEL) | VAF 122/320 reads (38%) | catalogued as rs779235094; called by pindel, varscan2
- FRMD1 | chr6:168081442 G>A | 5'Flank (SNP) | VAF 160/305 reads (52%) | catalogued as rs780805597; called by muse, mutect2, varscan2
- OPRM1 | c.1165-10679C>A | Intron (SNP) | VAF 24/66 reads (36%) | called by muse, varscan2
- PCDH11Y | c.3129+38T>C | Intron (SNP) | VAF 84/174 reads (48%) | called by muse, mutect2, varscan2
- SLC35E2A | n.1071G>A | RNA (SNP) | VAF 276/861 reads (32%) | called by muse, varscan2
- VNN3 | c.*103G>A | 3'UTR (SNP) | VAF 148/289 reads (51%) | catalogued as rs568114870; called by muse, mutect2, varscan2
